TARGET case TARGET-30-PALFDZ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/03d9ef07-e09b-5d36-83c2-1092c258e57a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.0 years (1,080 days); Year of diagnosis: 2001; Days to last follow up: 4,620 days (12.6 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PALFDZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
